Somatic mutation profile of tumor specimen 0DBFCG from CCDI case PBBLHI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 17.0 years (6,216 days).
Specimen 0DBFCG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51d11ed3-356c-46cc-8bd5-d32775af1220.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBFC9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6514acdc-903a-48ca-9f7e-96bb29ed52a0

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 2, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO9B | c.5812A>G p.T1938A | Missense Mutation (SNP) | VAF 253/720 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs969274842; called by muse, mutect2, varscan2
- OGDHL | c.1273G>A p.V425M | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs766131013; called by mutect2, varscan2
- SEC23A | c.606A>C p.E202D | Missense Mutation (SNP) | VAF 85/315 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as COSV56975090; called by muse, mutect2, varscan2
- ZBTB47 | c.1997G>A p.G666D | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749581589; called by muse, mutect2, varscan2
- EPHB1 | c.2833C>A p.Q945K | Missense Mutation (SNP) | VAF 86/725 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HAUS6 | c.1662G>T p.Q554H | Missense Mutation (SNP) | VAF 290/803 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- SHC2 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 78/202 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.677); called by muse, varscan2
- SPATA31A1 | c.1186C>T p.Q396* | Nonsense Mutation (SNP) | VAF 126/838 reads (15%) | called by muse, mutect2
- ZSCAN20 | c.1492C>T p.L498F | Missense Mutation (SNP) | VAF 185/621 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CELSR2 | c.8143+34C>G | Intron (SNP) | VAF 34/223 reads (15%) | called by muse, mutect2, varscan2
- FMN1 | c.2044-1456G>T | Intron (SNP) | VAF 157/440 reads (36%) | catalogued as rs763394475; called by muse, mutect2, varscan2
- SLC18A3 | c.-60G>T | 5'UTR (SNP) | VAF 3/21 reads (14%) | called by muse, varscan2
